Somatic mutation profile of tumor specimen HCM-CSHL-0460-C50-01B (aliquot HCM-CSHL-0460-C50-01B-02D-A79C-36) from HCMI case HCM-CSHL-0460-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.1 years (20,838 days).
Specimen HCM-CSHL-0460-C50-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93ffd654-38c8-47e3-a889-47d8bf04fb2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0460-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0460-C50-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf78454c-78f3-428b-aedf-2703d759276f

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Translation Start Site 1, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 67/354 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.827); catalogued as rs1228352007; called by muse, mutect2, varscan2
- CSMD1 | c.5986C>T p.P1996S (on ENST00000520002; = p.P1995S on NM_033225.6) | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746789823; called by muse, mutect2, varscan2
- DPP6 | c.1987C>T p.R663C (on ENST00000377770 / NM_001364500.2; = p.R601C on NM_001936.5) | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1443134542, COSV59600522; called by muse, mutect2, varscan2
- FAM78A | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs185462653; called by muse, mutect2, varscan2
- FAM83E | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs778652007, COSV50031609; called by mutect2, varscan2
- GOLGA6L2 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 51/398 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs780514194; called by muse, mutect2, varscan2
- GUF1 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55783438; called by muse, mutect2, varscan2
- MYH3 | c.5536C>T p.R1846W | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757418855, COSV56863601; called by mutect2, varscan2
- NR1H4 | c.1219C>G p.P407A (on ENST00000551379 / NM_001206993.2; = p.P393A on NM_005123.4) | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.521); catalogued as rs886556064; called by muse, mutect2
- PTPRU | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763919581; called by muse, mutect2
- SERPINA3 | c.869T>A p.M290K | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs939073700, COSV67586702; called by muse, mutect2
- SLIT3 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs751355143, COSV60590561; called by muse, mutect2
- ATRX | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 13/391 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.199); called by muse, mutect2
- CARNS1 | c.2386C>A p.P796T | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2
- CDH1 | c.1102dup p.T368Nfs*4 | Frame Shift Ins (INS) | VAF 32/167 reads (19%) | called by mutect2, varscan2
- EPG5 | c.4056G>A p.M1352I | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- EXPH5 | c.5385G>C p.K1795N | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.278); called by muse, mutect2
- GPRASP1 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 11/368 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2
- M6PR | c.213C>G p.Y71* | Nonsense Mutation (SNP) | VAF 34/256 reads (13%) | called by muse, mutect2, varscan2
- MYO16 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2
- MYT1L | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 15/443 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TSSK4 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- UBE2G1 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- WDR27 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- ZNF280C | c.1483T>C p.F495L | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AATK | c.3243G>A p.P1081= (on ENST00000326724 / NM_001080395.3; = p.P978= on NM_004920.2) | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as rs374173747; called by muse, mutect2, varscan2
- CDC42EP5 | c.405C>A p.R135= | Silent (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2
- CORO7 | c.483G>A p.L161= | Silent (SNP) | VAF 10/98 reads (10%) | called by mutect2, varscan2
- DOCK2 | c.4785G>A p.L1595= | Silent (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- PCDH9 | c.3105C>T p.F1035= | Silent (SNP) | VAF 10/280 reads (4%) | called by muse, mutect2
- SRSF8 | c.630G>A p.S210= | Silent (SNP) | VAF 37/610 reads (6%) | called by muse, mutect2
- TBC1D16 | c.1860C>T p.P620= | Silent (SNP) | VAF 39/183 reads (21%) | catalogued as rs376608231; called by muse, varscan2
- ZNF527 | c.1752T>C p.C584= | Silent (SNP) | VAF 32/270 reads (12%) | called by muse, mutect2, varscan2
- TRPM1 | c.213+91C>T | Intron (SNP) | VAF 15/396 reads (4%) | called by muse, mutect2
